Gene-level copy-number profile of tumor specimen TCGA-CM-6679-01A from TCGA case TCGA-CM-6679, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 58.9 years (21,519 days).
Specimen TCGA-CM-6679-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.9c463414-cc1a-4a2c-90ed-912919b43264.absolute_liftover.gene_level_copy_number.v36.tsv, workflow ABSOLUTE segment calls lifted over to GRCh38 (Affymetrix SNP 6.0); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 5,231 have no estimate.
https://portal.gdc.cancer.gov/files/409df494-4877-4cc0-9048-a90da48a42fa

Most common (modal) total copy number across autosomal genes: 5 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 1,204; copy number 3: 5,059; copy number 4: 14,352; copy number 5: 21,380; copy number 6: 5,539; copy number 7: 7,858.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CM-6679-01A-11D-1834-01): tumor purity 0.39, ploidy 5.02, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 11, i.e. more than twice the modal value of 5; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
